Somatic mutation profile of tumor specimen C3N-01897-01 (aliquot CPT0162300021) from CPTAC case C3N-01897, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 56.1 years (20,477 days).
Specimen C3N-01897-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7635dc2b-8963-4d0d-a834-a8681c17dd41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01897-31 (Blood Derived Normal), aliquot CPT0162360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fb3ab64-c235-4d0d-9888-005cef62ac9d

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Intron 4, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 109/405 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 159/331 reads (48%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASIC2 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 118/507 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs376380924; called by muse, mutect2, varscan2
- CFAP44 | c.5338C>T p.L1780F | Missense Mutation (SNP) | VAF 83/486 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762637939; called by muse, mutect2, varscan2
- DAXX | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 216/714 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs200527264; called by muse, mutect2, varscan2
- ESX1 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 112/485 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as rs200088361, COSV65423956; called by muse, varscan2
- FLT4 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 197/650 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753863393, COSV56117471; called by muse, mutect2, varscan2
- HMCN1 | c.9989G>A p.R3330Q | Missense Mutation (SNP) | VAF 118/350 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs780529619, COSV54878805; called by muse, mutect2, varscan2
- HRH4 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 148/365 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs775040150; called by muse, mutect2, varscan2
- KCNA3 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 226/522 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871329; called by muse, mutect2, varscan2
- NFATC2 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 166/614 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234960228, COSV65355992, COSV65356510; called by muse, mutect2, varscan2
- TKTL1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 151/311 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs201452569; called by muse, mutect2, varscan2
- UNC5A | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 189/616 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779405939; called by muse, mutect2, varscan2
- XDH | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 134/507 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs140879910; called by muse, mutect2, varscan2
- ASIC2 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 115/506 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP6V0A1 | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC18C | c.375C>G p.S125R | Missense Mutation (SNP) | VAF 102/1120 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.09); called by muse, mutect2
- DCAF12L2 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 172/354 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.071); called by muse, varscan2
- MFHAS1 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- PEAR1 | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 187/660 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SLC12A9 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 90/1354 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- HTT | c.1752C>T p.D584= | Silent (SNP) | VAF 118/380 reads (31%) | catalogued as rs368866386; called by muse, mutect2, varscan2
- KLHL29 | c.87C>T p.T29= | Silent (SNP) | VAF 222/828 reads (27%) | called by muse, mutect2, varscan2
- KRT37 | c.648C>T p.D216= | Silent (SNP) | VAF 245/848 reads (29%) | catalogued as rs766404637, COSV56658723; called by muse, mutect2, varscan2
- PCDHA9 | c.1662C>T p.F554= | Silent (SNP) | VAF 249/968 reads (26%) | catalogued as rs782760687, COSV65329339; called by muse, mutect2, varscan2
- SLC44A3 | c.18C>A p.A6= | Silent (SNP) | VAF 30/584 reads (5%) | called by muse, mutect2
- TMEM131L | c.4620G>A p.P1540= | Silent (SNP) | VAF 338/591 reads (57%) | catalogued as rs375188134; called by muse, mutect2, varscan2
- CDK14 | c.124-16967del | Intron (DEL) | VAF 153/565 reads (27%) | called by mutect2, pindel, varscan2
- CKS1B | c.59+82G>C | Intron (SNP) | VAF 167/574 reads (29%) | called by muse, mutect2, varscan2
- RAB3IP | c.936+28A>T | Intron (SNP) | VAF 155/636 reads (24%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1079G>C | Intron (SNP) | VAF 185/980 reads (19%) | catalogued as rs772225714; called by muse, mutect2, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 34/227 reads (15%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
- ZBTB8OS | c.*60G>A | 3'UTR (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
